Somatic mutation profile of tumor specimen BA2484D (aliquot aq-BA2484D) from BEATAML1.0 case 2218, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 24.8 years (9,050 days).
Specimen BA2484D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a409d339-632f-45fb-8a25-b1aac342b97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2436D (Solid Tissue Normal), aliquot aq-BA2436D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/344a92c4-3440-4716-8418-76d3ffdcdb32

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.4393C>T p.R1465* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs886040991, CD126766, CM060211, COSV71112190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 67/340 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADPRHL1 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100733504; called by muse, mutect2, varscan2
- GRIN2B | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV74204646, COSV74207603; called by muse, mutect2
- MYT1 | c.3299A>T p.N1100I | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs770187081; called by muse, mutect2, varscan2
- ATAD3A | c.1520T>A p.F507Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRY1 | c.1122G>C p.W374C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PGLYRP2 | c.297_304dup p.V102Dfs*40 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- TNKS1BP1 | c.4055A>G p.N1352S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZBTB32 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNFRSF1A | c.-32A>T | 5'UTR (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
